Somatic mutation profile of tumor specimen 0DMUZ9 from CCDI case PBCAWP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Atypical choroid plexus papilloma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.4 years (140 days).
Specimen 0DMUZ9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c3409a9-c1a5-4fd1-ab75-d98086e07d71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMUXG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95be147f-b128-463c-8002-91814940133e

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZFP57 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 83/783 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs77625743, CM083210, COSV65306439; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMY1C | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 210/1171 reads (18%) | catalogued as rs752371105, COSV64406893; called by muse, mutect2, varscan2
- C9 | c.907C>G p.L303V | Missense Mutation (SNP) | VAF 27/708 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99662115; called by muse, mutect2
